Gene-level copy-number profile of tumor specimen C3N-01493-04 from CPTAC case C3N-01493, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 35.0 years (12,770 days).
Specimen C3N-01493-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7fa00c96-48b0-4689-b604-564074ff33be.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01493-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/433f3f79-f853-42fd-aa19-5ed553c19439

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 550; copy number 1: 14,498; copy number 2: 38,101; copy number 3: 4,917; copy number 4: 372; copy number 5: 195; copy number 6: 27; copy number 7: 28; copy number 8: 112; copy number 9: 20; copy number 10: 3; copy number 11: 36; copy number 12: 19; copy number 13: 4; copy number 14: 5; copy number 15: 9.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–1): RPS3AP15.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr15:20,759,311–21,058,440, 17 genes (within-gene range 0–1): AC012414.2, AC012414.3, LONRF2P3, AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P.
- chr15:21,980,277–22,160,868, 13 genes: OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P, AC010760.1, RPS8P10, IGHV1OR15-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 458 genes in 54 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,173,141–1,523,962, 13 genes, copy number 5–12: CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075.
- chr5:4,866,521–5,376,836, 11 genes, copy number 5–7: AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1.
- chr5:5,395,378–5,396,968, 3 genes, copy number 5: MTCO1P30, MTCO2P30, MTCO1P31.
- chr5:8,207,019–8,561,682, 10 genes, copy number 5–8: AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1.
- chr5:106,415,576–107,011,052, 4 genes, copy number 5: AC027313.1, AC114940.1, AC114940.2, LINC01950.
- chr5:107,376,889–109,196,841, 13 genes, copy number 5 (within-gene range 2–5): EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17, AC133134.1, LINC01023, FER, AC034207.1, AC008871.1, Y_RNA, AC109481.1.
- chr5:110,289,233–111,997,464, 23 genes, copy number 5 (within-gene range 4–5): TMEM232, MIR548F3, AC008650.1, SLC25A46, AC008782.1, BCLAF1P1, AC010395.1, AC010395.2, TSLP, AC008572.1, WDR36, AC010468.2, RPS3AP21, CAMK4, AC010468.1, AC010275.1, STARD4, STARD4-AS1, HMGN1P13, AC008967.1, NREP, RN7SKP57, HMGN1P14.
- chr5:112,707,498–113,022,195, 9 genes, copy number 6 (within-gene range 4–6): APC, CBX3P3, RNU6-482P, AC008575.1, SRP19, REEP5, XBP1P1, ZRSR2P1, DCP2.
- chr5:124,636,913–125,602,227, 7 genes, copy number 5 (within-gene range 4–5): ZNF608, AC112196.1, AC113398.2, AC113398.1, LINC02240, AC109464.1, AC109464.2.
- chr5:125,350,868–125,968,085, 6 genes, copy number 5: RN7SKP117, AC109471.1, AC116362.2, AC010587.2, AC010587.1, RPSAP37.
- chr12:39,539,581–39,619,803, 3 genes, copy number 6: AC121334.2, ABCD2, AC121334.3.
- chr12:45,919,131–46,004,685, 2 genes, copy number 6: SCAF11, AC084878.1.
- chr12:49,292,631–49,527,425, 8 genes, copy number 7: AC125611.4, PRPH, TROAP, C1QL4, DNAJC22, SPATS2, AC125611.2, AC125611.1.
- chr12:50,841,498–50,887,884, 3 genes, copy number 8: RN7SL519P, TMPRSS12, AC013244.3.
- chr12:54,353,661–54,984,762, 18 genes, copy number 5–11 (within-gene range 1–11): AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1, VDAC1P5, MUCL1, TESPA1.
- chr12:55,426,254–55,716,043, 16 genes, copy number 5 (within-gene range 1–5): OR6C76, AC122685.1, OR6C2, OR6C70, OR6C68, OR6C64P, OR6C4, OR2AP1, OR6U2P, OR10P1, AC009779.4, OR10AE3P, PSMB3P1, AC009779.5, METTL7B, ITGA7.
- chr12:57,055,643–57,797,554, 48 genes, copy number 8–12 (within-gene range 3–12): NEMP1, NAB2, STAT6, LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3.
- chr12:58,087,892–59,064,238, 11 genes, copy number 5–8: LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1.
- chr12:59,586,793–59,789,855, 2 genes, copy number 5 (within-gene range 3–5): RNU4-20P, SLC16A7.
- chr12:60,341,824–60,363,935, 2 genes, copy number 5: Y_RNA, AC090022.1.
- chr12:65,645,992–66,170,072, 14 genes, copy number 5–8: PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4.
- chr12:66,950,754–69,354,234, 56 genes, copy number 8–14: AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1.
- chr12:69,449,470–72,728,844, 51 genes, copy number 6–15: LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr12:73,648,666–73,846,188, 4 genes, copy number 5–7: AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:73,906,940–74,049,981, 2 genes, copy number 7: AC136188.1, LINC02394.
- chr12:74,656,561–75,044,793, 4 genes, copy number 5–6 (within-gene range 4–6): AC123904.2, AC123904.1, AC123904.3, AC073525.1.
- chr12:75,649,195–75,967,062, 8 genes, copy number 5–7: AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1.
- chr12:76,721,534–76,853,696, 3 genes, copy number 5–6: RPL7P43, AC093014.1, ZDHHC17.
- chr12:83,661,009–84,294,562, 3 genes, copy number 6–9: AC093025.1, AC090679.2, AC090679.1.
- chr12:85,781,892–85,882,992, 3 genes, copy number 5–10: AC137768.1, RASSF9, NTS.
- chr12:87,746,567–88,199,887, 14 genes, copy number 5–9: AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3.
- chr12:89,919,437–90,300,974, 4 genes, copy number 5–8: BRWD1P2, LINC02399, AC126178.1, LINC02392.
- chr12:118,782,926–118,833,536, 2 genes, copy number 5: LINC02439, RNA5SP374.
- chr12:118,981,541–119,163,051, 3 genes, copy number 5 (within-gene range 4–5): SRRM4, AC087885.1, RN7SL508P.
- chr12:119,171,555–119,541,040, 7 genes, copy number 5 (within-gene range 2–5): HSPB8, AC084880.4, AC084880.3, AC084880.1, AC084880.2, LINC00934, CCDC60.
- chr12:128,793,194–128,827,579, 3 genes, copy number 5: SLC15A4, AC108704.2, AC108704.1.
- chr12:130,024,493–130,165,740, 9 genes, copy number 9: AC055717.2, LINC02418, AC135388.1, LINC02419, AC026336.4, AC026336.3, FZD10-AS1, AC026336.5, FZD10.
- chr12:130,337,887–130,877,678, 14 genes, copy number 5–8: PIWIL1, AC127071.2, AC127071.3, RIMBP2, AC063926.1, AC063926.3, AC063926.2, AC095350.1, AC073912.3, STX2, AC073912.1, AC073912.2, RNU6-1077P, RAN.
- chr14:103,519,667–103,733,668, 18 genes, copy number 5: CKB, AL133367.1, TRMT61A, RNU7-160P, AL139300.2, BAG5, KLC1, COA8, AL139300.1, RNU4-68P, AL049840.2, AL049840.6, AL049840.3, AL049840.4, AL049840.5, XRCC3, ZFYVE21, Y_RNA.
- chr14:105,890,084–105,896,577, 6 genes, copy number 5 (within-gene range 3–5): AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16.

Autosomal genes at a single copy (total copy number 1): 12,160. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
